Gene-level copy-number profile of tumor specimen ALCH-AEKT-TTP1-A from ALCHEMIST case ALCH-AEKT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.9 years (18,965 days).
Specimen ALCH-AEKT-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0deb16c8-001f-42c7-9e73-a2da90dd323d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEKT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/56e04bb9-fca6-41c5-8201-7a233fcb9e5b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 157; copy number 2: 57,683; copy number 3: 518; copy number 4: 4; copy number 30: 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:26,042,675–26,042,781, 1 gene (within-gene range 0–2): RNU6-942P.
- chr15:25,172,635–25,232,468, 33 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34.
- chr18:37,273,706–37,306,333, 2 genes (within-gene range 0–2): AC090386.1, AC090386.2.
- chr20:50,840,615–50,840,749, 1 gene (within-gene range 0–2): TMSB4XP6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:40,121,962–40,122,540, 1 gene, copy number 30: CDRT15P14.

Autosomal genes at a single copy (total copy number 1): 155. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
